Gene-level copy-number profile of tumor specimen TCGA-A2-A0EX-01A from TCGA case TCGA-A2-A0EX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.2 years (16,858 days).
Specimen TCGA-A2-A0EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5382306d-84ce-4839-acb5-ba11a8f8cea5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0EX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/042b00bd-488b-4631-b404-912f31f71478

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,443; copy number 2: 50,375; copy number 3: 2,443; copy number 4: 312; copy number 5: 469; copy number 6: 211; copy number 7: 43; copy number 8: 181; copy number 10: 187; copy number 11: 132; copy number 12: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0EX-01A-21D-A036-01): tumor purity 0.61, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,242 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:56,381,781–56,505,072, 4 genes, copy number 8: HMGN1P17, LINC01948, AC008391.1, RPL26P19.
- chr5:56,536,583–56,537,826, 1 gene, copy number 8: AC022431.1.
- chr8:26,383,054–28,227,562, 45 genes, copy number 7–8: BNIP3L, AC011726.1, DNAJB6P2, AC011726.2, PNMA2, DPYSL2, PSME2P5, ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3, AC021678.1.
- chr8:30,382,119–31,220,984, 19 genes, copy number 12: RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6.
- chr8:34,784,028–36,779,209, 19 genes, copy number 7–10: LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264.
- chr8:36,795,255–36,795,862, 1 gene, copy number 10: AC124076.1.
- chr8:37,326,575–39,105,445, 64 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr8:40,900,016–41,896,762, 25 genes, copy number 5–10: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P.
- chr8:60,516,936–61,501,645, 15 genes, copy number 10 (within-gene range 3–10): RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1.
- chr8:62,110,524–64,583,627, 35 genes, copy number 5–8 (within-gene range 5–10): NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22.
- chr8:65,377,592–109,899,762, 715 genes, copy number 5–10 (broad region; genes not listed).
- chr8:112,222,928–119,480,775, 51 genes, copy number 6 (within-gene range 2–6): CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3.
- chr8:119,711,830–135,742,495, 241 genes, copy number 6–11 (broad region; genes not listed).
- chr8:135,977,329–135,980,588, 1 gene, copy number 10: AC103955.1.
- chr8:141,968,091–141,968,841, 1 gene, copy number 5: AC104417.1.
- chr8:143,437,659–143,563,062, 5 genes, copy number 5: ZC3H3, AC067930.9, AC067930.3, RN7SKP175, GSDMD.

Autosomal genes at a single copy (total copy number 1): 3,022. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
